Somatic mutation profile of tumor specimen TCGA-DG-A2KH-01A (aliquot TCGA-DG-A2KH-01A-21D-A22X-09) from TCGA case TCGA-DG-A2KH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: GX; Age at diagnosis: 25.2 years (9,209 days).
Specimen TCGA-DG-A2KH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1dc6563-7f42-428e-94c7-5302f6a1018c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DG-A2KH-10A (Blood Derived Normal), aliquot TCGA-DG-A2KH-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb2f39a5-09e3-457e-8b06-595cb488cfdd

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 14, Frame Shift Ins 3, Intron 1, Splice Site 1, Nonsense Mutation 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.3263C>A p.A1088E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV62325835; called by muse, mutect2
- BACH1 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV54521100; called by muse, mutect2, varscan2
- CAVIN3 | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV58269796; called by muse, mutect2, varscan2
- CCDC141 | c.3271G>A p.E1091K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55382261, COSV99041206; called by muse, mutect2, varscan2
- CEP44 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56660341, COSV56660758; called by muse, mutect2, varscan2
- CXCL8 | c.64+2dup p.X22_splice | Splice Site (INS) | VAF 26/65 reads (40%) | catalogued as rs779261613, COSV100266363; called by mutect2, pindel, varscan2
- DERL1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52366277; called by muse, mutect2, varscan2
- DPYSL5 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV56516187; called by muse, mutect2, varscan2
- EGFL6 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs969155152, COSV63635308; called by muse, mutect2
- FAM78B | c.288G>C p.L96F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57981231, COSV57983553; called by muse, mutect2
- FFAR4 | c.350T>G p.V117G | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV65179783; called by muse, mutect2, varscan2
- GPC4 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63697606; called by muse, mutect2, varscan2
- HDAC4 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs745953691, COSV61876034; called by muse, mutect2, varscan2
- IPO9 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV55226216; called by muse, mutect2, varscan2
- JUP | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs781883243, COSV60277536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK6 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1308172914, COSV54581230; called by muse, mutect2, varscan2
- KIF1A | c.2824C>T p.R942C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57485669; called by muse, mutect2, varscan2
- KIF7 | c.3974G>A p.R1325Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs73477443, COSV51546832; called by muse, mutect2, varscan2
- KPNA1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60271089; called by muse, mutect2, varscan2
- LZTR1 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1346699262, COSV53151687; called by muse, mutect2, varscan2
- MAGEB10 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.406); catalogued as COSV63312688; called by muse, mutect2, varscan2
- MST1R | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV56565180; called by muse, mutect2, varscan2
- MUC16 | c.29969G>A p.R9990K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.065); catalogued as COSV101200386, COSV67492792; called by muse, mutect2, varscan2
- MUC16 | c.28528G>A p.E9510K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.351); catalogued as COSV67464284; called by muse, mutect2
- NDUFA8 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as rs760549929, COSV65653683; called by muse, mutect2, varscan2
- PAF1 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as COSV55396227; called by muse, mutect2, varscan2
- PCSK7 | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV100309432, COSV56121011; called by muse, mutect2, varscan2
- PDCD7 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs779528128, COSV52600626; called by muse, mutect2, varscan2
- PGAP2 | c.587C>T p.S196L (on ENST00000463452 / NM_001346398.2; = p.S257L on NM_014489.4) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs766716423, COSV53466672; called by muse, mutect2, varscan2
- PKP3 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368733672; called by muse, mutect2, varscan2
- POGK | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV63312460; called by muse, mutect2, varscan2
- PRKAA2 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.608); catalogued as rs991680488, COSV64806594; called by muse, mutect2, varscan2
- PSD | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs762779182, COSV50061055; called by muse, mutect2, varscan2
- PWWP2A | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs758270619, COSV61048046; called by muse, mutect2, varscan2
- RYR2 | c.5941G>A p.D1981N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV63712818; called by muse, mutect2, varscan2
- SCPEP1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs1414519099, COSV51855598; called by muse, mutect2, varscan2
- SERPINA10 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56227581; called by muse, mutect2, varscan2
- SETMAR | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as COSV62781496; called by muse, mutect2, varscan2
- SLC6A17 | c.1580C>G p.S527W | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100521028, COSV58992500; called by muse, mutect2, varscan2
- SLC6A3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs138948519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX19 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as COSV56288639; called by muse, mutect2, varscan2
- STXBP1 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64815405; called by muse, mutect2, varscan2
- TRAF1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as rs757877072, COSV65869364; called by muse, mutect2, varscan2
- TRPM3 | c.4237G>A p.E1413K (on ENST00000357533 / NM_001366142.2; = p.E1268K on NM_020952.6) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.111); catalogued as COSV62594632; called by muse, mutect2, varscan2
- WT1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as COSV60083413; called by muse, mutect2, varscan2
- ZNF512 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.788); catalogued as COSV100820923; called by muse, mutect2
- ZRANB2 | c.245delinsAA p.R82Kfs*5 | Frame Shift Ins (INS) | VAF 14/74 reads (19%) | catalogued as COSV54674365; called by mutect2*, pindel, varscan2*
- HCFC1 | c.4415_4435del p.I1472_S1478del | In Frame Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- SLC9A3 | c.2031_2032insA p.A678Sfs*50 | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | called by mutect2, pindel*, varscan2
- TMEM185A | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ZRANB2 | c.246dup p.S83Ifs*4 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by mutect2, varscan2
- AHNAK2 | c.4161C>T p.L1387= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV60930272; called by muse, mutect2, varscan2
- BCDIN3D | c.141C>T p.L47= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs1365431636, COSV61702840; called by muse, mutect2, varscan2
- CAPN12 | c.649C>T p.L217= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs59420559, COSV61014841, COSV61018655; called by muse, mutect2, varscan2
- DLEC1 | c.177C>T p.F59= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as rs751255103, COSV57306510; called by muse, mutect2, varscan2
- GREB1 | c.2391A>G p.R797= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV99303535; called by muse, mutect2
- IGLV3-1 | c.303G>A p.E101= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs549842612; called by muse, mutect2, varscan2
- KLHDC7A | c.120G>A p.S40= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs1399021358, COSV68770986; called by muse, mutect2, varscan2
- KLRG2 | c.933G>T p.A311= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV61800682, COSV61801615; called by muse, mutect2, varscan2
- MYC | c.372C>T p.F124= (on ENST00000377970; = p.F139= on NM_002467.6) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV52378454; called by mutect2, varscan2
- PCDH15 | c.5544C>T p.C1848= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as COSV57308361, COSV57391897; called by muse, mutect2, varscan2
- PCDHA8 | c.63C>T p.L21= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs1222164678, COSV65336098, COSV65340411; called by muse, mutect2, varscan2
- RHPN2 | c.924G>A p.V308= | Silent (SNP) | VAF 91/168 reads (54%) | catalogued as COSV54284641; called by muse, mutect2, varscan2
- SACS | c.1641G>A p.P547= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs370143541; called by muse, mutect2, varscan2
- TAF4 | c.2832C>T p.L944= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as rs1297541125, COSV53343133; called by muse, mutect2, varscan2
- MACF1 | c.15832-9566A>T | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as rs1446904618, COSV57143581; called by muse, mutect2
- XIST | n.8727T>C | RNA (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
